Somatic mutation profile of tumor specimen TCGA-44-3919-01A (aliquot TCGA-44-3919-01A-02D-1105-08) from TCGA case TCGA-44-3919, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.4 years (26,081 days).
Specimen TCGA-44-3919-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e44aa3c5-c177-4499-8b95-3c5c6db4e780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3919-10A (Blood Derived Normal), aliquot TCGA-44-3919-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b635cad7-32d0-497b-bb81-99beff246299

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, Splice Site 1, 5'UTR 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 34/140 reads (24%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARHGEF28 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1279203645, COSV55264986, COSV55269258; called by muse, mutect2, varscan2
- CELSR3 | c.7996G>T p.E2666* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV50992177; called by muse, mutect2
- CEP97 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59126648; called by muse, mutect2, varscan2
- ESYT2 | c.1520C>A p.T507K (on ENST00000613624; = p.T431K on NM_020728.3) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51754742; called by muse, mutect2, varscan2
- GLG1 | c.2847C>A p.F949L | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as rs746630548, COSV52671930; called by muse, mutect2, varscan2
- GPR45 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV51525523; called by muse, mutect2
- GRWD1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53520111; called by mutect2, varscan2
- ITSN1 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67157438; called by muse, mutect2, varscan2
- MC5R | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201991586, COSV61255313; called by muse, mutect2, varscan2
- MYH7B | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 161/423 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53423440; called by muse, mutect2, varscan2
- OPHN1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV62785198; called by muse, mutect2, varscan2
- PAQR9 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV61417486; called by muse, mutect2, varscan2
- PAX1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV68271127, COSV68271602; called by muse, mutect2, varscan2
- PLD2 | c.1536C>G p.S512R | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV54008166; called by muse, mutect2, varscan2
- PRDM16 | c.689T>C p.F230S | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV54602637; called by muse, mutect2, varscan2
- PREPL | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752887453, COSV53218389; called by muse, mutect2, varscan2
- PTN | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV61967933; called by muse, mutect2, varscan2
- RTN2 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55595393; called by muse, mutect2
- SLC26A3 | c.1588T>C p.Y530H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); catalogued as COSV60641726; called by muse, mutect2, varscan2
- UGT1A3 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 100/431 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs757870746, COSV59394925; called by muse, mutect2, varscan2
- WDR91 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs868274411, COSV60371322; called by muse, mutect2, varscan2
- ZDHHC8 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs750523517, COSV57712127; called by muse, mutect2, varscan2
- ZNF558 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256254386, COSV56864045; called by muse, mutect2, varscan2
- KHNYN | c.1353del p.H451Qfs*27 | Frame Shift Del (DEL) | VAF 38/195 reads (19%) | called by mutect2, pindel, varscan2
- MEPCE | c.1672-6_1684del p.X558_splice | Splice Site (DEL) | VAF 36/284 reads (13%) | called by mutect2, pindel
- PLEKHG7 | c.13_18del p.E5_S6del | In Frame Del (DEL) | VAF 14/80 reads (18%) | called by pindel, varscan2
- UXS1 | c.1066del p.D356Mfs*15 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- AATF | c.930A>G p.T310= | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- FILIP1 | c.612G>A p.L204= | Silent (SNP) | VAF 63/334 reads (19%) | catalogued as COSV52737158; called by muse, mutect2, varscan2
- FRYL | c.75T>G p.A25= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV51956380; called by muse, mutect2, varscan2
- KIF22 | c.1986T>C p.C662= | Silent (SNP) | VAF 84/487 reads (17%) | catalogued as rs1156657476, COSV50717097; called by muse, mutect2, varscan2
- MAML3 | c.2724G>C p.G908= | Silent (SNP) | VAF 129/552 reads (23%) | catalogued as COSV72209799; called by muse, mutect2, varscan2
- NETO1 | c.1560T>C p.S520= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV55011993; called by muse, mutect2, varscan2
- SH3PXD2B | c.2256G>A p.Q752= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as rs1488951850, COSV61128772; called by muse, mutect2, varscan2
- TMPRSS6 | c.2326C>T p.L776= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs756171282, COSV60982232; called by muse, varscan2
- NRXN1 | c.3365-109857C>T | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PLEKHG7 | c.-2T>C | 5'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, varscan2
